Somatic mutation profile of tumor specimen 0DOG3I from CCDI case PBCCGK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.9 years (1,440 days).
Specimen 0DOG3I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0afe8a5-6309-4efd-89d0-e01e485e6fdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOG2Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f88b5965-f3a8-4b99-8c0e-356d68d67108

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDIT3 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 108/423 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762234408; called by muse, mutect2, varscan2
- FAM234A | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 25/418 reads (6%) | catalogued as rs769062990; called by muse, mutect2
- TSPYL6 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 116/470 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs749908739, COSV57817852; called by muse, mutect2, varscan2
- ATXN1L | c.1136C>A p.S379* | Nonsense Mutation (SNP) | VAF 83/336 reads (25%) | called by muse, mutect2, varscan2
- LRP1B | c.9343A>G p.K3115E | Missense Mutation (SNP) | VAF 28/561 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2
- FAM53C | chr5:138338212 T>G | 5'Flank (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
